Gene-level copy-number profile of specimen HCM-WCMC-1281-C67-85A from HCMI case HCM-WCMC-1281-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 36.1 years (13,184 days).
Specimen HCM-WCMC-1281-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ab35f12a-c838-43f6-b33e-11777e0ddebd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1281-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/3154b36a-51c8-4b0c-a253-188cd501dc57

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 440; copy number 1: 3,423; copy number 2: 32,263; copy number 3: 15,611; copy number 4: 6,732; copy number 5: 433; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,290,071–12,318,316, 2 genes: DEFB131D, DEFB130A.
- chr9:65,282,101–65,285,209, 1 gene: FOXD4L5.
- chr17:46,372,855–46,487,141, 1 gene: NSFP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 434 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,822,664–205,357,090, 15 genes, copy number 5: AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10.
- chr1:207,880,972–208,736,286, 9 genes, copy number 5: CD34, AL356275.1, PLXNA2, AL590138.1, AL606753.1, LINC01735, LINC02769, RPS26P13, LINC01717.
- chr1:232,983,435–248,937,043, 353 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:141,055,290–141,060,596, 1 gene, copy number 5: AC100860.1.
- chr10:46,753,605–46,832,476, 6 genes, copy number 5: CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P.
- chr10:47,918,739–47,923,524, 1 gene, copy number 5 (within-gene range 5–8): NPY4R2.
- chr10:48,064,308–48,119,455, 1 gene, copy number 5: PTPN20CP.
- chr16:55,760,566–55,793,960, 1 gene, copy number 6: CES1P1.
- chr19:45,733,439–45,815,308, 8 genes, copy number 5: BHMG1, SIX5, AC074212.1, DM1-AS, DMPK, AC011530.1, DMWD, RSPH6A.
- chr21:24,154,871–26,573,286, 39 genes, copy number 5: AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1.

Autosomal genes at a single copy (total copy number 1): 1,003. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
